Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6Y0, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6Y0-01B (Primary Tumor).

[page 1 of 3]
ICD-O-3

Adenocarcinoma NOS
8140/3
Site Esophagus, distal third
0155
JW 8/8/13

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) GASTRIC CARDIA:

Fragments of oxyntic/fundic mucosa with mild inactive chronic gastritis.
No intestinal metaplasia or Helicobacter pylori-like microorganisms identified (H & E stain).
No tumor identified.

(B) DISTAL ESOPHAGUS:

SUPERFICIAL FRAGMENTS OF MODERATELY DIFFERENTIATED ADENOCARCINOMA.
Depth of invasion cannot be determined.
Separate fragment of squamocolumnar junction mucosa with active chronic inflammation.

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) GASTRIC CARDIA - Multiple tan-pink irregular fragments of tissue (0.5 x 0.3 x 0.2 cm in aggregate). Toto in A.
(B) DISTAL ESOPHAGUS - Multiple tan-pink irregular fragments of tissue (1.0 x 0.6 x 0.6 cm in aggregate). Toto in B.

CLINICAL HISTORY

Esophageal carcinoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to report the results of HER-2/*neu* FISH

Addendum completed by

SPECIMEN SOURCE

Distal esophagus

SUMMARY

Tissue section of the adenocarcinoma was evaluated for HER-2/*neu* gene amplification by interphase fluorescence in situ hybridization technique using the HER-2/*neu* (HER-2/*neu* CEP17

Slide adequacy is satisfactory. Sixty tumor nuclei were counted and showed an average of 1.90 copies of HER-2/*neu* gene per nucleus and an average of 1.40 copies of CEP17 per nucleus.

Negative and positive controls (established by with this batch are appropriate.

Two representative images have been archived.

INTERPRETATION

The tumor cells demonstrated **no amplification** of the HER-2/*neu* gene copy levels (HER-2/*neu*: CEP17 signal ratio: 1.36)

*The following guideline has been established for HER-2/*neu* testing:
Normal HER-2/*neu* levels: < 1.80; equivocal HER-2/*neu* levels: 1.80 – 2.20; amplified HER-2/*neu* levels: > 2.20
(Ref: Arch Pathol Lab Med. 2007; 131:18-43)*

NOTES

The HER-2/*neu* probe is specific for the HER-2/*neu* gene Locus (17q 11.2-q12) and the CEP 17 DNA probe is specific for the alpha satellite DNA sequence at the centromeric region of Chromosome 17 (17 p11.1 -q11.2).

This test has been cleared and approved for specific uses by the U.S. Food and Drug Administration. Its system is operating within the performance specifications stated in the product insert.

Entire report and diagnosis completed by:

-----END OF REPORT-----

[page 3 of 3]
Page: 3

Specimen Date/Time:

Met Malignancy History		/
Time/Synchronous Primary N. Jctd		/
Reviewed by Initials	JAC	4/16/2013

Source: NCI Genomic Data Commons file 7a0cfe22-a223-496a-b30b-1eb9d4bc23d7 (TCGA-R6-A6Y0.79266CC6-C63C-4383-AB93-3A6FADBA6958.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).